Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4301, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4301-01A (Primary Tumor).

■
Diagnosis/diagnoses:

1. and 2.: Soft-tissue and peritoneal metastases of a poorly differentiated adenocarcinoma.

Total gastrectomy preparation with the inclusion of an ulcerated poorly differentiated cardiac adenocarcinoma with a maximum diameter of 4 cm, with infiltration of the perigastric soft tissue and sparse involvement of the cross-striated muscle (evidently of the diaphragm). Six regional lymph metastases. The tumor extends into the oral resection margin. Tumor-free duodenal resection margin with evidence of heterotopic gastric mucosa islands. Tumor-free omentum.

Tumor stage: pT4 pN1 (6/18/ pM1 ■

Source: NCI Genomic Data Commons file bd863231-18ca-4f31-921b-9a6d1b25050b (TCGA-CG-4301.71AD2B68-59B3-4449-B2AE-F0B04BF0C93B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).